Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9V5, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9V5-01A (Primary Tumor).

(MM/DD/YYYY)

ICD-0-3

Adenocarcinoma, mucinous
endocervical type 8482/3

Site: Cervix NOS C53.9

W 3/7/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

"Biopsy of cervix"

Mucinous adenocarcinoma of endocervical type moderately differentiated.

Immunohistochemistry exam requested to improve evaluation.

Immunohistochemistry exam:

Immunohistochemistry profile supports primary neoplasia of uterine cervix.

Source: NCI Genomic Data Commons file 0bd81ce3-9f4c-4c8a-abb0-365607989370 (TCGA-VS-A9V5.3EF810E0-17D2-4D40-9D81-29D896915C92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).